Somatic mutation profile of tumor specimen TCGA-IQ-A61L-01A (aliquot TCGA-IQ-A61L-01A-11D-A30E-08) from TCGA case TCGA-IQ-A61L, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage II; Tumor grade: G1; Age at diagnosis: 72.6 years (26,506 days).
Specimen TCGA-IQ-A61L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73143d1f-9ac8-4f3f-9fbc-9b9f5f759a3d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IQ-A61L-10A (Blood Derived Normal), aliquot TCGA-IQ-A61L-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c13cd3b-b478-4b5f-b6ee-4f9c919aa571

The open-access MAF lists 90 somatic variants for this specimen: 69 protein-altering or splice-affecting, 20 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 20, Nonsense Mutation 6, Frame Shift Del 2, Frame Shift Ins 2, In Frame Del 1, Intron 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 35/101 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 22/101 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ABL1 | c.937A>G p.I313V | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100583881, COSV100584596; called by muse, mutect2, varscan2
- AFF3 | c.3182C>A p.A1061D | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100418650; called by muse, mutect2, varscan2
- AL136295.1 | c.2447G>C p.*816Sext*26 | Nonstop Mutation (SNP) | VAF 11/142 reads (8%) | catalogued as COSV99937942; called by muse, mutect2
- ALPK2 | c.5869C>T p.H1957Y | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100864313; called by muse, mutect2, varscan2
- APBB2 | c.2158C>T p.R720* (on ENST00000295974 / NM_001166050.2; = p.R721* on NM_004307.2) | Nonsense Mutation (SNP) | VAF 23/143 reads (16%) | catalogued as rs1560589921, COSV55948589; called by muse, mutect2, varscan2
- B3GAT3 | c.854T>A p.L285Q | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99605881; called by muse, mutect2, varscan2
- BAG3 | c.407C>T p.S136L | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV100958220; called by muse, mutect2, varscan2
- BMP2K | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.162); catalogued as rs1245387246, COSV100621685; called by muse, mutect2, varscan2
- BTN3A1 | c.139G>C p.D47H | Missense Mutation (SNP) | VAF 13/179 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99175759; called by muse, mutect2
- CAP2 | c.1039G>C p.E347Q | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.08); catalogued as COSV100012367; called by muse, mutect2, varscan2
- CCNT1 | c.1066G>C p.A356P | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.548); catalogued as COSV99980690; called by muse, mutect2, varscan2
- CD1E | c.775G>A p.V259I | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as rs764692539, COSV63769980; called by muse, mutect2, varscan2
- CHD8 | c.3274C>T p.R1092C (on ENST00000646647 / NM_001170629.2; = p.R813C on NM_020920.4) | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1439223724, COSV67870139; called by muse, mutect2, varscan2
- CHST12 | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 72/204 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as rs750508134, COSV99324431; called by muse, mutect2, varscan2
- CKM | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.061); catalogued as COSV55534859, COSV99675525; called by muse, mutect2, varscan2
- COL19A1 | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 23/101 reads (23%) | catalogued as rs756283130, COSV59565037; called by muse, mutect2, varscan2
- CRYBG1 | c.3947C>T p.S1316L | Missense Mutation (SNP) | VAF 34/193 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs763975227, COSV64810833; called by muse, mutect2, varscan2
- CYP26B1 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50014890; called by muse, mutect2, varscan2
- DOP1B | c.4421G>C p.R1474T | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV101215277; called by muse, mutect2
- DPM2 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1049674525, COSV55948259; called by muse, mutect2, varscan2
- FBXW2 | c.740A>T p.D247V | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100535182; called by muse, mutect2, varscan2
- FHDC1 | c.2083C>G p.Q695E | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV99471209; called by muse, mutect2, varscan2
- FREM2 | c.7043T>A p.I2348K | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV99748425; called by muse, mutect2
- H3C6 | c.168G>C p.Q56H | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.068); catalogued as COSV100839015; called by muse, mutect2, varscan2
- HDAC9 | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as rs759089852, COSV101286711; called by muse, mutect2, varscan2
- HECTD4 | c.7637G>A p.R2546Q | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.642); catalogued as rs371361328; called by muse, mutect2, varscan2
- ICE1 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.135); catalogued as COSV99664514; called by muse, mutect2, varscan2
- IRF8 | c.477C>G p.I159M | Missense Mutation (SNP) | VAF 19/261 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.104); catalogued as COSV99236355; called by muse, mutect2
- ITIH3 | c.2417C>T p.T806M | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs184153550, COSV69650592; called by muse, mutect2, varscan2
- JAK2 | c.201C>G p.I67M | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as COSV67612621; called by muse, mutect2, varscan2
- KIAA1109 | c.2336C>A p.S779Y | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as COSV52695346, COSV99156803; called by muse, mutect2, varscan2
- KIR3DL2 | c.1346C>A p.S449* | Nonsense Mutation (SNP) | VAF 56/274 reads (20%) | catalogued as COSV99551990; called by muse, varscan2
- KMT2E | c.5230C>T p.H1744Y | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV57571791; called by muse, mutect2, varscan2
- LAMA4 | c.2546G>C p.R849T (on ENST00000230538 / NM_001105206.3; = p.R842T on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.053); catalogued as COSV100038212; called by muse, mutect2
- MCC | c.410C>G p.S137C | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100202479; called by muse, varscan2
- MCC | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV100202481; called by muse, varscan2
- MOB1A | c.121C>G p.L41V | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.746); catalogued as COSV101247251; called by muse, mutect2, varscan2
- MPP4 | c.541A>G p.R181G | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100206800; called by muse, mutect2, varscan2
- NEDD4L | c.2045T>A p.L682H (on ENST00000400345 / NM_001144967.3; = p.L662H on NM_015277.6) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99894521; called by muse, mutect2, varscan2
- NLRP2 | c.1343G>A p.R448Q | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as rs371780675, COSV54757680; called by muse, mutect2, varscan2
- NSMF | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs989048174, COSV52999001; called by muse, mutect2, varscan2
- ORC3 | c.409C>T p.Q137* | Nonsense Mutation (SNP) | VAF 31/95 reads (33%) | catalogued as COSV100005846; called by muse, mutect2, varscan2
- PGR | c.1085C>T p.A362V | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.129); catalogued as COSV99678168; called by muse, mutect2, varscan2
- PLK2 | c.188C>T p.S63L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV57107088, COSV57111206; called by muse, mutect2
- PRAG1 | c.1962G>A p.W654* | Nonsense Mutation (SNP) | VAF 25/97 reads (26%) | catalogued as COSV100422111; called by muse, mutect2, varscan2
- PRRC2A | c.4316G>C p.R1439P | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV101051146, COSV101051320; called by muse, mutect2, varscan2
- PSG3 | c.610C>G p.L204V | Missense Mutation (SNP) | VAF 156/488 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as COSV100548915; called by muse, mutect2, varscan2
- RBP7 | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV99606002; called by muse, mutect2
- RCC1 | c.514G>A p.V172M | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs773841273, COSV100868109; called by muse, mutect2, varscan2
- RFX6 | c.2231G>C p.C744S | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.042); catalogued as rs774495117, COSV100263641, COSV60584799; called by muse, mutect2, varscan2
- SAMD9 | c.3497C>T p.S1166F | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV101180202; called by muse, mutect2, varscan2
- SF3B3 | c.3292G>A p.G1098R | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1340318422, COSV100209801; called by muse, mutect2, varscan2
- SMTN | c.2632G>A p.E878K | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as rs758896914, COSV100294225; called by muse, mutect2, varscan2
- SPACA1 | c.331C>T p.R111W | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751066460, COSV52759409; called by muse, mutect2, varscan2
- SSBP3 | c.6T>G p.F2L | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV100669276; called by muse, mutect2, varscan2
- STK16 | c.314C>T p.T105M | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs750325229, COSV50282650, COSV99850467; called by muse, mutect2, varscan2
- TLR10 | c.2158G>C p.E720Q | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV100457585, COSV58300915; called by muse, mutect2, varscan2
- TOPORS | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 11/100 reads (11%) | catalogued as COSV100745156; called by muse, mutect2, varscan2
- UGT2B4 | c.977C>T p.S326L | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.27); catalogued as COSV100522106; called by muse, mutect2, varscan2
- YLPM1 | c.5243G>A p.R1748Q | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as rs1437349238, COSV99459384; called by muse, mutect2, varscan2
- ZNF564 | c.400C>G p.Q134E | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.445); catalogued as COSV100213093, COSV59435788; called by muse, mutect2, varscan2
- ADGRG3 | c.707_720del p.E236Gfs*7 | Frame Shift Del (DEL) | VAF 10/66 reads (15%) | called by mutect2, pindel, varscan2
- CASP8 | c.78_125del p.S26_L42delinsR | In Frame Del (DEL) | VAF 33/66 reads (50%) | called by mutect2, pindel
- CSTA | c.283_292del p.L95Ffs*22 | Frame Shift Del (DEL) | VAF 34/140 reads (24%) | called by mutect2, pindel, varscan2
- KNL1 | c.5944dup p.M1982Nfs*6 (on ENST00000346991 / NM_170589.5; = p.M1956Nfs*6 on NM_144508.5) | Frame Shift Ins (INS) | VAF 36/165 reads (22%) | called by mutect2, pindel, varscan2
- LRCH3 | c.2007dup p.L670Vfs*8 | Frame Shift Ins (INS) | VAF 92/247 reads (37%) | called by mutect2, pindel, varscan2
- SLC12A5 | c.2726C>T p.A909V (on ENST00000454036 / NM_001134771.2; = p.A886V on NM_020708.5) | Missense Mutation (SNP) | VAF 136/289 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- ALG3 | c.492C>T p.V164= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as COSV99891102; called by muse, mutect2, varscan2
- CACNA1H | c.4962C>T p.Y1654= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs57204601, COSV61997012; called by muse, varscan2
- CCDC15 | c.1851C>T p.S617= | Silent (SNP) | VAF 16/129 reads (12%) | catalogued as COSV100776961; called by muse, mutect2, varscan2
- CFAP44 | c.1926C>T p.G642= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs1401516779, COSV99869378; called by muse, mutect2, varscan2
- COPG1 | c.1593C>T p.Y531= | Silent (SNP) | VAF 33/74 reads (45%) | catalogued as rs769977893, COSV100135554; called by muse, mutect2, varscan2
- EZHIP | c.921G>A p.A307= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as rs1390635778, COSV100539645; called by muse, mutect2, varscan2
- GGT7 | c.1053C>T p.F351= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV100321900; called by muse, mutect2, varscan2
- GPRASP2 | c.109A>C p.R37= | Silent (SNP) | VAF 34/258 reads (13%) | catalogued as COSV100176693; called by muse, mutect2, varscan2
- IRS2 | c.3276G>A p.K1092= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs1216633484, COSV101019007; called by muse, mutect2, varscan2
- KMT2A | c.354C>G p.V118= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV100628593; called by muse, mutect2
- LRRK1 | c.2748G>A p.L916= | Silent (SNP) | VAF 65/217 reads (30%) | catalogued as COSV99439306; called by muse, mutect2, varscan2
- MIEF2 | c.39C>T p.S13= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as rs138649022; called by muse, mutect2, varscan2
- MYO15A | c.4221G>A p.R1407= | Silent (SNP) | VAF 34/98 reads (35%) | catalogued as COSV52755400, COSV99232369; called by muse, mutect2, varscan2
- OTUD5 | c.852G>A p.E284= | Silent (SNP) | VAF 82/262 reads (31%) | catalogued as COSV99331898; called by muse, mutect2, varscan2
- PKP2 | c.723C>T p.L241= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV99297607; called by muse, mutect2, varscan2
- SHROOM4 | c.3159G>T p.L1053= | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as COSV99173316; called by muse, mutect2, varscan2
- VAT1 | c.402G>A p.V134= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as rs962580213, COSV100849708; called by muse, mutect2, varscan2
- WAPL | c.3045C>T p.I1015= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as rs773048925, COSV99556432; called by muse, mutect2, varscan2
- WIZ | c.3924C>T p.G1308= (on ENST00000673675 / NM_001371589.1; = p.G213= on NM_021241.3) | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as rs774882608, COSV54611545; called by muse, mutect2, varscan2
- ZEB1 | c.2689C>A p.R897= | Silent (SNP) | VAF 27/62 reads (44%) | catalogued as COSV100314217, COSV58041247; called by muse, mutect2, varscan2
- DST | c.4297-2372T>C | Intron (SNP) | VAF 29/100 reads (29%) | catalogued as COSV99754725; called by muse, mutect2, varscan2
